Somatic mutation profile of tumor specimen C3L-02121-06 (aliquot CPT0114100009) from CPTAC case C3L-02121, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 39.0 years (14,259 days).
Specimen C3L-02121-06: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51f43956-ac8d-4875-a276-72007d7f9856.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02121-31 (Blood Derived Normal), aliquot CPT0116060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b56fcbca-6202-45b8-a4b7-9b14c433356c

The open-access MAF lists 52 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Nonsense Mutation 3, Intron 1, In Frame Ins 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 232/596 reads (39%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 164/489 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 166/629 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs786201995, CM110141, CM993669, COSV64288588, COSV64289716, COSV64295411; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADD3 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 156/574 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs774062682, COSV53322049; called by muse, mutect2, varscan2
- COL5A3 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 109/336 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.53); catalogued as rs753274164; called by muse, mutect2, varscan2
- FBLN1 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 49/913 reads (5%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.979); catalogued as rs761373665, COSV59935842; called by muse, mutect2
- FOXA2 | c.581C>T p.P194L (on ENST00000377115 / NM_153675.3; = p.P200L on NM_021784.5) | Missense Mutation (SNP) | VAF 308/874 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65796262; called by muse, mutect2, varscan2
- GDF10 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 147/515 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs1555207438; called by muse, mutect2, varscan2
- LRP5 | c.1346C>G p.S449C | Missense Mutation (SNP) | VAF 288/776 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.95); catalogued as rs759951621, COSV53711002; called by muse, mutect2, varscan2
- ME3 | c.1555C>A p.Q519K | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs771830027; called by muse, mutect2, varscan2
- MRPL18 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 200/630 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100364669; called by muse, mutect2, varscan2
- PIK3R1 | c.1356_1358dup p.N453dup (on ENST00000521381 / NM_181523.3; = p.N183dup on NM_181504.4) | In Frame Ins (INS) | VAF 33/118 reads (28%) | catalogued as COSV57140765, COSV99073794; called by mutect2, pindel, varscan2
- PLXNA1 | c.4556C>T p.P1519L | Missense Mutation (SNP) | VAF 281/834 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs768988256, COSV52524857, COSV52529034; called by muse, mutect2, varscan2
- PSD2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 189/456 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs374016750; called by muse, mutect2, varscan2
- SMCHD1 | c.3023C>T p.T1008M | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs771100083; called by muse, mutect2, varscan2
- SMG1 | c.7214G>A p.R2405H | Missense Mutation (SNP) | VAF 281/698 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs376829789; called by muse, mutect2, varscan2
- THOP1 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs368086026; called by muse, mutect2
- UBE2NL | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 191/549 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs782151716; called by muse, mutect2, varscan2
- URB1 | c.5750A>G p.N1917S | Missense Mutation (SNP) | VAF 182/506 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs374514405, COSV60566530; called by muse, mutect2, varscan2
- VASN | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 226/567 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs775449844; called by muse, mutect2, varscan2
- WDR24 | c.503G>A p.R168Q (on ENST00000248142; = p.R106Q on NM_032259.4) | Missense Mutation (SNP) | VAF 239/655 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as rs1264468504; called by muse, mutect2, varscan2
- ATG16L2 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 22/522 reads (4%) | called by muse, mutect2
- CCDC150 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 111/343 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCDC30 | c.1522A>G p.S508G (on ENST00000340612; = p.S465G on NM_001080850.3) | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- DOCK2 | c.3967-1G>T p.X1323_splice | Splice Site (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- FRY | c.3983G>A p.R1328K | Missense Mutation (SNP) | VAF 136/356 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GDF6 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 506/1397 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAPTM4A | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NLRP14 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 152/435 reads (35%) | called by muse, mutect2, varscan2
- NPY1R | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- PCDHGB2 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 342/924 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC27A6 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- STAC | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TGFB3 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 279/800 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGIF1 | c.2dup p.M1? (on ENST00000330513 / NM_001374396.1; = p.M21Ifs*36 on NM_003244.4) | Frame Shift Ins (INS) | VAF 186/595 reads (31%) | called by mutect2, pindel, varscan2
- TMEM184B | c.446T>G p.I149S | Missense Mutation (SNP) | VAF 20/499 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2
- ZSCAN25 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 216/584 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by mutect2, varscan2
- DCAF4L2 | c.348G>A p.P116= | Silent (SNP) | VAF 201/578 reads (35%) | catalogued as rs778714529, COSV100150901, COSV60477312; called by muse, mutect2, varscan2
- KIF1A | c.1879C>T p.L627= | Silent (SNP) | VAF 202/591 reads (34%) | called by muse, mutect2, varscan2
- MYO16 | c.4323C>T p.D1441= | Silent (SNP) | VAF 301/775 reads (39%) | catalogued as rs1351763934; called by muse, mutect2, varscan2
- OLFM2 | c.282C>T p.R94= | Silent (SNP) | VAF 303/925 reads (33%) | catalogued as rs150005775; called by muse, mutect2, varscan2
- PADI6 | c.333C>T p.P111= | Silent (SNP) | VAF 201/558 reads (36%) | catalogued as rs775337851; called by muse, mutect2, varscan2
- PEX11B | c.307C>T p.L103= | Silent (SNP) | VAF 144/414 reads (35%) | catalogued as rs183685874; called by muse, mutect2, varscan2
- RERE | c.2412G>A p.P804= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1023188795; called by muse, mutect2, varscan2
- SOX3 | c.1194C>T p.R398= | Silent (SNP) | VAF 149/430 reads (35%) | catalogued as COSV65168351; called by muse, mutect2, varscan2
- SPIN2A | c.675C>A p.I225= | Silent (SNP) | VAF 182/591 reads (31%) | called by muse, mutect2, varscan2
- SSX3 | c.378G>T p.V126= | Silent (SNP) | VAF 170/473 reads (36%) | called by muse, mutect2, varscan2
- TTK | c.33G>A p.L11= | Silent (SNP) | VAF 64/202 reads (32%) | called by muse, mutect2, varscan2
- ZBTB12 | c.300C>T p.I100= | Silent (SNP) | VAF 222/591 reads (38%) | called by muse, mutect2, varscan2
- ZNF318 | c.933C>T p.L311= | Silent (SNP) | VAF 67/205 reads (33%) | catalogued as rs1210594310, COSV58934119; called by muse, mutect2, varscan2
- ZNF626 | c.972C>T p.Y324= | Silent (SNP) | VAF 171/469 reads (36%) | called by muse, mutect2, varscan2
- ENAH | c.803-579_803-578del | Intron (DEL) | VAF 126/426 reads (30%) | called by mutect2, pindel, varscan2
